PECGS case C083-000060 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/85e99876-5d79-48b6-ae5c-df9e2856e7ef

Demographics
Sex at birth: female; Age at index: 62 years; Year of birth: 1959; Education level: High School Graduate or GED.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 61.7 years (22,536 days); AJCC clinical stage: Stage IV; AJCC pathologic stage: Stage IVA; Progression or recurrence: yes; Days to last follow up: 582 days (1.6 years).

Other clinical attributes
- Menopause status: Postmenopausal.

Biospecimens (2 samples)
- Sample C083-000060_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000060_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
